Gene-level copy-number profile of tumor specimen TCGA-13-0894-01B from TCGA case TCGA-13-0894, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.3 years (19,466 days).
Specimen TCGA-13-0894-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3b931696-b77d-417d-b187-50aef6ece607.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0894-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/f4533a76-a643-4531-8677-c21a087a0bcc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 3,094; copy number 3: 20,449; copy number 4: 12,066; copy number 5: 15,229; copy number 6: 5,415; copy number 7: 2,170; copy number 8: 613; copy number 9: 354; copy number 10: 5; copy number 11: 321; copy number 12: 101.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:9,753,404–10,182,928, 3 genes (within-gene range 0–3): GRIN2A, AC007218.2, AC007218.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,564 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,931,506–34,165,842, 103 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:148,028,046–198,222,513, 905 genes, copy number 7–8 (broad region; genes not listed).
- chr7:14,145,049–14,974,777, 1 gene, copy number 7 (within-gene range 5–7): DGKB.
- chr7:14,814,131–16,530,580, 16 genes, copy number 7 (within-gene range 5–7): AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3.
- chr7:126,438,598–142,332,701, 349 genes, copy number 7 (broad region; genes not listed).
- chr8:103,121,032–145,066,685, 620 genes, copy number 9–11 (broad region; genes not listed).
- chr10:34,109,560–34,815,325, 1 gene, copy number 9 (within-gene range 6–9): PARD3.
- chr10:34,488,583–37,784,131, 52 genes, copy number 9: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1.
- chr10:37,791,580–37,796,109, 2 genes, copy number 9: AL132657.2, ZNF33BP1.
- chr10:43,628,817–43,674,703, 1 gene, copy number 8 (within-gene range 4–8): ZNF32-AS3.
- chr10:43,643,860–56,596,031, 226 genes, copy number 7–12 (broad region; genes not listed).
- chr10:64,620,374–94,362,959, 595 genes, copy number 7–8 (broad region; genes not listed).
- chr10:109,864,766–111,498,941, 33 genes, copy number 7 (within-gene range 4–7): XPNPEP1, RNU4-5P, ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5, RPL7P35, SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1, BTBD7P2, AC021035.1, RPS6P15.
- chr10:114,109,856–126,798,708, 219 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:127,734,562–129,380,753, 16 genes, copy number 7–10: AL391005.1, FOXI2, BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1, MKI67, LINC01163, AL390763.1, LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1.
- chr17:142,789–4,366,628, 171 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:32,631,625–42,063,969, 254 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
